Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3712, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3712-01A (Primary Tumor).

Diagnosis:

This is a poorly differentiated adenocarcinoma of the colon (descending/sigmoid colon) of histopathological differentiation grade G3, with ulceration of the inner surface of the tumor, peritumorous, chronic recurrent concomitant inflammation, focal mucus formation, tumor infiltration in the parietal layers of the colon as far as the subserous fatty connective tissue, with twelve local lymph node metastases (12/18), with carcinomatous lymphangitis and carcinosis of the blood vessels. In addition the overview slices from the resection margins show these to be tumor-free, and the sigmoid colon shows diverticulosis.

According to the sections available, the tumor spread of the colon carcinoma corresponds to a tumor stage of pT3, pN2, MX, L1, V1.

Source: NCI Genomic Data Commons file 5f3c8fd1-3a3a-4c06-b3c2-0ee0f1aa9df9 (TCGA-AA-3712.DEA49ACF-C268-4547-AE88-D7A5CFDB5808.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).